Gene-level copy-number profile of tumor specimen TCGA-66-2757-01A from TCGA case TCGA-66-2757, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 65.7 years (24,014 days).
Specimen TCGA-66-2757-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.946cdb75-d53b-4178-811b-c0a5769f39c5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2757-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/941b547e-c12c-42df-b3a1-617eef801dd6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,721; copy number 2: 34,027; copy number 3: 9,148; copy number 4: 914; copy number 5: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2757-01A-01D-0844-01): tumor purity 0.86, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:49,496,763–49,741,321, 3 genes, copy number 5: AC090155.2, AC090155.1, PSAT1P1.
- chr11:114,517,864–114,595,786, 5 genes, copy number 5: AC020549.3, NXPE1, AC020549.1, NXPE4, AC020549.2.

Autosomal genes at a single copy (total copy number 1): 15,721. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
